Gene-level copy-number profile of tumor specimen TCGA-15-1449-01A from TCGA case TCGA-15-1449, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.2 years (23,828 days).
Specimen TCGA-15-1449-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.03355f92-2b6c-4580-a6e5-a475e3690817.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-15-1449-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/382b974b-7934-47bf-832c-5cfbe73dfbce

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 821; copy number 3: 7,967; copy number 4: 21,354; copy number 5: 19,784; copy number 6: 2,220; copy number 7: 4,425; copy number 8: 81; copy number 9: 6; copy number 10: 3,015; copy number 16: 7; copy number 18: 5; copy number 28: 5; copy number 36: 129.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-15-1449-01): tumor purity 0.47, ploidy 5.56, whole-genome doublings 2 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,167 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:179,794,958–185,052,614, 129 genes, copy number 36 (broad region; genes not listed).
- chr5:172,479,274–172,697,720, 7 genes, copy number 16: AC011407.1, LINC01944, AC027309.3, NEURL1B, AC027309.2, MIR5003, AC027309.1.
- chr5:173,292,517–173,362,240, 4 genes, copy number 18: RNA5SP200, STC2, MIR8056, RNU6-500P.
- chr5:173,689,459–173,705,849, 1 gene, copy number 18: LINC01942.
- chr7:70,972–159,233,377, 3,014 genes, copy number 10 (broad region; genes not listed).
- chr15:26,543,546–26,970,385, 6 genes, copy number 9: GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.
- chr15:39,250,684–39,254,845, 1 gene, copy number 10: C15orf54.
- chr15:42,412,823–42,491,141, 1 gene, copy number 28 (within-gene range 3–28): ZNF106.
- chr15:42,491,233–42,548,802, 4 genes, copy number 28: SNAP23, AC018362.1, AC018362.3, LRRC57.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
